Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7081, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7081-01A (Primary Tumor).

[page 1 of 2]
TCGA-HC-7081

☒ Surgical Pathology

DEPARTMENT OF PATHOLOGY

PATIENT: [REDACTED] SPECIMEN: [REDACTED]
BIRTHDATE: [REDACTED] AGE: [REDACTED] SEX: [REDACTED]

MRN: [REDACTED] Rm #: [REDACTED] PHYSICIAN: [REDACTED]

PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO: [REDACTED]

Pre-Op Diagnosis
Prostate cancer
Post-Op Diagnosis
Same

Clinical History

Nothing indicated on requisition

Gross Description:

Container labeled "[REDACTED] - prostate" is a previously inked previously partially sectioned prostate gland with attached bilateral seminal vesicles. The specimen as received weighs 51 grams. On reconstruction the prostate gland is 5.5 x 4.9 x 4.6 cm and has a slightly shaggy lobulated outer surface. The urethra is approximately 4.2 x 0.4 x 0.4 cm and patent. The cut surface shows a slightly nodular rubbery gray tan to pink fibrotic cut surface. Noted in the right lateral lobe in the distal region there is a poorly defined approximately 1.0 x 0.9 x 0.8 cm area of tan gray fibrosis which grossly extends to within 0.1 cm of the inked outer surface margin. In the mid region of the specimen in the left posterior lobe there is a second poorly defined approximately 1.4 x 1.2 x 1.0 cm area of poorly defined tan gray fibrosis with slight induration. This grossly extends focally to within 0.1 cm of the nearest outer surface margin. No additional gross lesions are identified. A more distal area of fibrosis is seen to focally extend to within 0.2 cm of the apical (distal) margin in the right lateral lobe. The more central area is greater than 1.5 cm from the nearest proximal (vesical) margin. The seminal vesicles together are 6.0 x 2.2 x 1.0 cm. Each has a lobular outer surface with a multi-cystic gray pink fibrotic cut surface.

Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted as labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J -

[page 2 of 2]
left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle.

Microscopic Description:

Sections of the prostate show 70-80% of the prostate to be involved by a poorly differentiated adenocarcinoma. The neoplasm grows as raggedly infiltrating glands and as numerous individual glands infiltrating into the stroma. The neoplastic cells have enlarged nuclei with prominent nucleoli. Numerous areas of perineural invasion are seen. The neoplasm extends to the inked margin at the apical margin and the shaved vesicle margin from the base. The neoplasm also extends through the capsule in several areas and the inked margin is involved by neoplasm along several sections from the right prostate. Focal areas of neoplasia are seen within the right and left seminal vesicles as well as their origin.

Final Diagnosis

Prostate, radical prostatectomy:

Tumor characteristics:

Histologic type: Adenocarcinoma

Gleason grade:

Primary pattern: 4

Secondary pattern: 5

Total score: 9, focal Gleason 3 pattern

Tumor involves: Both lobes, 70% of the gland involved by neoplasm.

Seminal vesicle involvement: Yes, right and left.

Extracapsular tumor extension: Yes

Lymphovascular space invasion: Yes

Perineural space invasion: Yes

Surgical margin status:

Bladder neck margin: Positive

Apical (inferior) distal margin: Positive

Inked prostatic margin: Positive

Lymph node status:

No lymph nodes examined.

Other:

Stage: pT3bNx PAS 9 SPC-A

Comments

This test has been finalized at the Campus.

<Sign Out Dr. Signature>

Source: NCI Genomic Data Commons file 4e615cb5-7e56-48d9-b578-be9f2b159e24 (TCGA-HC-7081.75D1573A-CBF6-4B3C-93C4-2D410586884C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).